Gene-level copy-number profile of tumor specimen TCGA-AG-3586-01A from TCGA case TCGA-AG-3586, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage III; Age at diagnosis: 72.7 years (26,542 days).
Specimen TCGA-AG-3586-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-READ.ae534c14-575b-4cbe-aace-9d54c0db7095.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AG-3586-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0dc075c7-5d69-478a-b570-a14e710fa380

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 97; copy number 1: 2,645; copy number 2: 52,540; copy number 3: 3,055; copy number 4: 1,474.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-AG-3586-01): tumor purity 0.75, ploidy 2.09, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 97 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:4,787,332–5,128,412, 4 genes: PAICSP4, AC019176.1, AC019176.2, SNORA70.
- chr10:87,859,158–88,049,823, 6 genes: KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1.
- chr12:51,809,705–52,015,889, 12 genes: AC068987.1, TMDD1, AC068987.2, FIGNL2, AC068987.3, FIGNL2-DT, ANKRD33, AC025259.2, ACVRL1, ACVR1B, RNU6-574P, TAMALIN.
- chr18:50,959,267–57,371,731, 75 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2,635. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
